Gene-level copy-number profile of tumor specimen HCM-CSHL-0839-C34-06A from HCMI case HCM-CSHL-0839-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 65.3 years (23,837 days).
Specimen HCM-CSHL-0839-C34-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d22f55e7-2f70-4451-98dc-78df76f81389.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0839-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/ee2e5cc7-3f1e-48ae-afc4-9a7262034359

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 13,069; copy number 2: 30,899; copy number 3: 10,703; copy number 4: 2,940; copy number 5: 695; copy number 6: 52; copy number 7: 5; copy number 9: 12; copy number 10: 8.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,455,740, 16 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 772 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:206,159,585–206,162,928, 5 genes, copy number 7 (within-gene range 2–7): EEF1B2, AC007383.3, snoZ196, SNORD51, SNORA41.
- chr3:167,478,684–198,123,232, 596 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr10:23,694,746–28,408,251, 75 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr10:28,652,630–29,736,959, 20 genes, copy number 6: RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93, LYZL1, SVIL-AS1, PTCHD3P1, SVIL, MIR604, SNORD115, MIR938, CKS1BP2, RNU6-908P.
- chr10:31,033,089–31,143,813, 1 gene, copy number 9: AL359546.1.
- chr10:32,446,140–32,882,874, 1 gene, copy number 6 (within-gene range 2–6): CCDC7.
- chr10:32,887,273–34,875,422, 24 genes, copy number 6–10: ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1.
- chr10:35,008,551–36,442,392, 26 genes, copy number 6: CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2.
- chr20:8,077,251–8,968,360, 3 genes, copy number 5 (within-gene range 1–5): PLCB1, PHKBP1, PLCB1-IT1.
- chr20:13,008,972–13,638,932, 8 genes, copy number 5 (within-gene range 2–5): SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2.
- chr20:19,000,709–20,360,703, 13 genes, copy number 5 (within-gene range 4–5): AL135936.1, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1.

Autosomal genes at a single copy (total copy number 1): 12,734. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
